Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A3EV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A3EV-06A (Metastatic).

FINAL DIAGNOSIS:

Collection Date:

**PART 1: LYMPH NODE, "NODULE ADJACENT TO SUPERIOR VENA CAVA", BIOPSY -
TWO FRAGMENTS OF LYMPH NODE WITH NO SIGNIFICANT ABNORMALITY. NO EVIDENCE OF MALIGNANT
MELANOMA.**

**PART 2: LUNG, "RIGHT LOWER LOBE MASS", WEDGE RESECTION -
METASTATIC MALIGNANT MELANOMA ASSOCIATED WITH ANGIOLYMPHATIC INVASION. NO EVIDENCE OF
VISCERAL PLEURAL INVASION. ALL MARGINS FREE.**

*** PART 3: LYMPH NODE, "MASS ON PERICARDIUM", BIOPSY -
METASTATIC MALIGNANT MELANOMA INVOLVING A SOLITARY LYMPH NODE. NO DEFINITIVE EVIDENCE OF
EXTRACAPSULAR SPREAD.**

PATIENT HISTORY:

The patient is a *r* man.
PRE-OP DIAGNOSIS: Lung carcinoma.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Thoracoscopy.

Prior Malignancy History	Rec'd INTER-OP	☒
	fw	11/4/11

ICD-0-3

Melanoma, NOS 8720/3

CQCF Site: lymph node, NOS C77.9

Path pericardium C38.0

*fw
11/4/11*

Source: NCI Genomic Data Commons file efe03560-f4a3-47cd-8723-6c739255f179 (TCGA-ER-A3EV.DB3E0EA0-11E9-4803-ADD9-61D79908BD1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).